Somatic mutation profile of tumor specimen TCGA-ZJ-AB0I-01A (aliquot TCGA-ZJ-AB0I-01A-11D-A42O-09) from TCGA case TCGA-ZJ-AB0I, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Age at diagnosis: 26.0 years (9,486 days).
Specimen TCGA-ZJ-AB0I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b69b5e8-ce68-4a43-befc-d59ccab57067.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-AB0I-10A (Blood Derived Normal), aliquot TCGA-ZJ-AB0I-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b67c9c2c-6405-4789-b365-fc7c24091c4c

The open-access MAF lists 111 somatic variants for this specimen: 88 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 21, Frame Shift Del 4, Nonsense Mutation 4, Splice Site 2, Splice Region 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 35/45 reads (78%) | catalogued as rs1085307466, CM1110266, COSV100480555; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55285541; called by muse, mutect2, varscan2
- ALMS1 | c.9368T>C p.L3123P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.311); catalogued as COSV100042796; called by muse, mutect2, varscan2
- ANO7 | c.925C>G p.R309G (on ENST00000274979; = p.R255G on NM_001370694.2) | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99238655; called by muse, mutect2, varscan2
- ASB9 | c.55T>G p.F19V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100995530; called by muse, mutect2, varscan2
- ATAD1 | c.693C>T p.V231= | Splice Region (SNP) | VAF 6/12 reads (50%) | catalogued as COSV100058273; called by muse, mutect2
- ATPAF1 | c.637C>G p.Q213E (on ENST00000574428; = p.Q236E on NM_022745.4) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV100236233; called by muse, mutect2, varscan2
- BCDIN3D | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV100445465, COSV100445543; called by muse, mutect2, varscan2
- BEST4 | c.331T>G p.S111A | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as COSV100944025; called by muse, mutect2, varscan2
- BFSP1 | c.872A>G p.D291G | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV100925379; called by muse, mutect2, varscan2
- CAMK2A | c.237C>G p.I79M | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV100804562; called by muse, mutect2, varscan2
- CCDC144A | c.102C>A p.D34E | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV100502084; called by muse, mutect2, varscan2
- CEP350 | c.6764A>T p.K2255I | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV100854866; called by muse, mutect2, varscan2
- CLIP3 | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV99495778; called by muse, mutect2, varscan2
- CSMD1 | c.538C>G p.H180D | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as rs749221297, COSV101221602; called by muse, mutect2, varscan2
- CUX2 | c.724A>C p.I242L | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99919951; called by muse, mutect2, varscan2
- CYP4B1 | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as COSV99597228; called by muse, mutect2, varscan2
- DYNC2LI1 | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as COSV99571286; called by muse, mutect2, varscan2
- EDRF1 | c.2383G>T p.A795S (on ENST00000356792 / NM_001202438.2; = p.A761S on NM_015608.2) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.981); catalogued as COSV100523577, COSV61763552; called by muse, mutect2, varscan2
- EPHB1 | c.2491C>T p.Q831* | Nonsense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as COSV101213297; called by muse, mutect2, varscan2
- EXOSC10 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.608); catalogued as rs757576637, COSV58667960; called by muse, mutect2, varscan2
- FAM78B | c.494G>C p.R165T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100597645; called by muse, mutect2, varscan2
- FBH1 | c.620A>G p.E207G (on ENST00000362091 / NM_178150.3; = p.E258G on NM_032807.4) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.527); catalogued as COSV100758791; called by muse, mutect2, varscan2
- FSIP1 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as rs772046954, COSV100618130; called by muse, mutect2, varscan2
- GAS2 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.367); catalogued as COSV53410008, COSV99535239; called by muse, mutect2, varscan2
- GGT1 | c.148T>G p.C50G | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99959009; called by muse, mutect2, varscan2
- GKAP1 | c.955A>C p.K319Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100897393; called by muse, mutect2, varscan2
- GLYATL1 | c.835C>A p.Q279K (on ENST00000317391 / NM_001354699.1; = p.Q310K on NM_080661.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV55608386; called by muse, mutect2, varscan2
- GNAI1 | c.752A>G p.D251G | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100650546; called by muse, mutect2, varscan2
- GNRHR | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753280668, COSV56933293; called by muse, mutect2, varscan2
- GPRASP1 | c.141G>T p.M47I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.531); catalogued as COSV100851023; called by muse, mutect2, varscan2
- GPRASP1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV100851024; called by muse, mutect2, varscan2
- GRIN2B | c.2899G>C p.E967Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.241); catalogued as COSV101663079; called by muse, mutect2, varscan2
- HYDIN | c.9909C>G p.I3303M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101156852; called by muse, mutect2, varscan2
- IGDCC3 | c.2354C>A p.P785H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100031226; called by muse, mutect2, varscan2
- IGSF9 | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100829639; called by muse, mutect2, varscan2
- INTS6L | c.2485A>G p.R829G | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV100878144, COSV66084726; called by mutect2, varscan2
- ITK | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs146738280; called by muse, mutect2, varscan2
- ITM2A | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs776653962, COSV100964463; called by muse, mutect2, varscan2
- KDR | c.3685C>T p.R1229* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as rs763426023, COSV99817989; called by muse, mutect2, varscan2
- KMT2E | c.2399A>G p.E800G | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99996483; called by muse, mutect2, varscan2
- MAGEA3 | c.151G>T p.G51W | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100939062; called by muse, mutect2, varscan2
- MAPKAPK5 | c.544A>C p.T182P | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101612893; called by muse, mutect2, varscan2
- MROH2B | c.1901C>G p.S634* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV101270744; called by muse, mutect2, varscan2
- MTHFR | c.744C>G p.I248M | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100928233; called by muse, mutect2, varscan2
- MUC16 | c.7312G>T p.D2438Y | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.979); catalogued as rs112457736, COSV101200231; called by muse, mutect2, varscan2
- MUC17 | c.11978C>T p.T3993I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV100073839; called by muse, mutect2, varscan2
- MUC4 | c.15556G>A p.A5186T (on ENST00000463781 / NM_018406.7; = p.A950T on NM_004532.6) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100205135; called by muse, mutect2, varscan2
- MUC5B | c.14255C>A p.P4752H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.091); catalogued as COSV101500443; called by muse, mutect2, varscan2
- MUL1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1456100592, COSV51641509; called by muse, mutect2, varscan2
- MYH11 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs757255183, COSV55548758; called by muse, mutect2, varscan2
- NBAS | c.5474C>G p.S1825C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV99870284; called by muse, mutect2, varscan2
- NOL4L | c.964G>C p.A322P | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV100675636; called by muse, mutect2, varscan2
- OR5W2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs750353731, COSV60614549, COSV60616410; called by muse, mutect2, varscan2
- PGLYRP4 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.097); catalogued as rs547753918, COSV100668433; called by muse, mutect2, varscan2
- PHF1 | c.525C>G p.D175E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100992638; called by muse, mutect2, varscan2
- PLAG1 | c.535G>T p.G179W | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100387991; called by muse, mutect2, varscan2
- PLXND1 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as rs915985679, COSV100139508; called by muse, mutect2, varscan2
- POLG | c.855+1G>T p.X285_splice | Splice Site (SNP) | VAF 39/54 reads (72%) | catalogued as COSV99174857; called by muse, mutect2, varscan2
- PRF1 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV64615762; called by muse, mutect2, varscan2
- RCHY1 | c.219G>C p.Q73H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100185877; called by muse, mutect2, varscan2
- REXO1 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV99402417; called by muse, varscan2
- SFMBT1 | c.1436T>A p.V479D | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV99966193; called by muse, mutect2, varscan2
- SH3BP4 | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs373202308; called by muse, mutect2, varscan2
- SMG7 | c.2419C>A p.Q807K | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV100750385; called by muse, mutect2, varscan2
- TAF1D | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs200414618, COSV58680298; called by muse, mutect2, varscan2
- TANC2 | c.2896G>T p.V966F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101267518; called by muse, mutect2, varscan2
- TCTN2 | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs1566243238, COSV100315261; called by muse, mutect2, varscan2
- THNSL2 | c.591G>C p.E197D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV100147524; called by muse, mutect2, varscan2
- THOC1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1255057456, COSV99863454, COSV99863617; called by muse, mutect2, varscan2
- THSD7A | c.854A>T p.K285M | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.364); catalogued as COSV101448770; called by muse, mutect2, varscan2
- TRIB1 | c.974A>G p.E325G | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100322519; called by muse, mutect2, varscan2
- TRUB2 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306741, COSV55957319; called by muse, mutect2, varscan2
- USH2A | c.8957A>G p.H2986R | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV100237039; called by muse, mutect2, varscan2
- USP28 | c.3020G>C p.R1007T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV99135577; called by muse, mutect2, varscan2
- VCP | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100734248; called by muse, mutect2, varscan2
- XPO1 | c.2567A>G p.N856S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs768499033, COSV101294238; called by muse, mutect2, varscan2
- ZDBF2 | c.2557C>G p.Q853E | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV100985025; called by muse, mutect2, varscan2
- ZNF106 | c.4517C>T p.S1506L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); catalogued as rs749272671, COSV99782740; called by muse, mutect2, varscan2
- ZNF277 | c.1123C>G p.H375D | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100702461; called by muse, mutect2, varscan2
- ZNF395 | c.805C>G p.P269A | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100734004; called by muse, mutect2, varscan2
- ZNF594 | c.983G>T p.C328F | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV101280509; called by muse, mutect2, varscan2
- ABCC4 | c.75-33_84del p.X25_splice | Splice Site (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel
- BRCA1 | c.3528_3537del p.F1177Afs*30 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- DDX43 | c.723_754del p.C241* | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel
- RBM48 | c.809_831del p.A270Dfs*14 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- TMCC2 | c.1364_1374del p.E455Afs*19 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- TSC22D4 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2
- ADNP2 | c.1836T>A p.I612= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100080965; called by muse, mutect2, varscan2
- AHNAK | c.12945G>A p.K4315= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs1225999522, COSV99948000; called by muse, mutect2, varscan2
- BAZ2A | c.3153T>C p.S1051= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV99466617; called by muse, mutect2, varscan2
- CCDC9B | c.1107C>G p.A369= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV101233529; called by muse, mutect2, varscan2
- CMYA5 | c.11682C>A p.S3894= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV101405665; called by muse, mutect2, varscan2
- COL6A6 | c.1008C>T p.A336= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs200753152, COSV62041367; ClinVar: likely benign; called by muse, mutect2, varscan2
- DMD | c.2136G>A p.R712= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV99923337; called by muse, mutect2, varscan2
- IFIH1 | c.1620C>G p.A540= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs1428640918, COSV99718687; called by muse, mutect2, varscan2
- IGSF3 | c.2322C>T p.V774= (on ENST00000369486 / NM_001007237.3; = p.V794= on NM_001542.4) | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV59589695; called by muse, varscan2
- KRTAP12-3 | c.111C>T p.P37= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs1387918181, COSV59978977; called by muse, mutect2, varscan2
- MAGEC3 | c.1221T>C p.P407= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100025585; called by muse, mutect2, varscan2
- OR6T1 | c.261G>T p.T87= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100190029, COSV100190121, COSV58305548, COSV58310228; called by muse, mutect2, varscan2
- PORCN | c.300C>T p.S100= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV58226763; called by muse, mutect2, varscan2
- RBM33 | c.3435C>T p.H1145= | Silent (SNP) | VAF 26/27 reads (96%) | catalogued as rs775839923, COSV100355296; called by muse, mutect2, varscan2
- SEC14L5 | c.747T>C p.L249= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV99229010; called by muse, mutect2, varscan2
- SIM1 | c.975C>T p.I325= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV53493141; called by muse, mutect2, varscan2
- SMS | c.69A>G p.L23= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs761129868, COSV101048100; called by muse, mutect2, varscan2
- TTN | c.13809G>C p.T4603= (on ENST00000591111; = p.T3676= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100617916, COSV59972759; called by muse, mutect2, varscan2
- XKR4 | c.1840C>A p.R614= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100532947, COSV59332367; called by muse, mutect2, varscan2
- ZNF208 | c.300G>A p.L100= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV101237061; called by muse, mutect2, varscan2
- ZNF496 | c.1602C>T p.H534= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as rs552879014, COSV99665786; called by muse, mutect2, varscan2
- C10orf90 | c.1243+1163C>T | Intron (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99504326; called by muse, mutect2
- MROH8 | c.-307G>C | 5'UTR (SNP) | VAF 28/66 reads (42%) | catalogued as COSV54121751, COSV99457451, COSV99457732; called by muse, mutect2, varscan2
